Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5456, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5456-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Lymph node resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Amend/Addenda

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-5456

PATHOLOGIC DIAGNOSIS:

LEFT KIDNEY, NEPHRECTOMY (1330g):
RENAL CELL CARCINOMA, clear cell type (12.0 cm), Fuhrman nuclear grade III/IV,
involving the lower pole.

The soft tissue margins are negative for tumor.
The renal artery, vein, and ureter margins are negative for tumor.
The tumor is confined to the kidney.
Hale's colloidal iron is negative in tumor cells.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

AJCC Classification (6th Edition): pT2 N0 MX.

REGIONAL LYMPH NODES, LYMPH NODE DISSECTION:
Seven lymph nodes, negative for tumor (0/7).

CLINICAL DATA:
History: [REDACTED] with L renal mass
Operation: Left radical nephrectomy.
Clinical Diagnosis: Left renal mass.

TISSUE SUBMITTED:
A/1. Left kidney.
B/2. Regional lymph node.

CROSS DESCRIPTION:
The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "Left kidney", consists of a left radical nephrectomy specimen (1330 gm; 25.0 x 12.0 x 10.0 cm) with a ureter (13.5 x 0.4 cm), a vein (27.0 x 0.5 cm) that wraps around the specimen, and a renal artery (16.1 cm, 0.6 cm). A mass (11.5 x 10.0 x 12.0 cm) replaces the lower pole and is 13.0 cm from the ureter margin, 25 cm away from the vein margin, 15.0 cm away from the artery margin, and 0.5 cm from the peri-renal fat. The mass is a mixture of areas of golden yellow (T1) and brown (T2) and white (T3) tumor. The tumor is adjacent to but does not invade the renal vein. The tumor compresses the architecture of the collecting system without invasion of the pelvis or calyces. The entire lower pole is enlarged. No adrenal tissue or lymph nodes are identified. The peri-renal fat is inked black. The renal cortex (1 cm thick) is poorly defined from the medulla. Representative sections of tumor and normal tissue are submitted to the tumor bank. Representative sections of kidney are submitted for electron microscopy and immunofluorescence. Representative sections of tumor are submitted for cytogenetics.

Micro A1-A3: Sections of tumor (T1-T3) from Tissue Bank.
Micro A4: Vein margin.
Micro A5: Artery margin.
Micro A6: Ureter margin.
Micro A7-A8: Tumor with respect to closest inked margin.
Micro A9: Tumor and adjacent uninvolved kidney.
Micro A10: Tumor and adjacent renal vessels.
Micro A11-A12: Additional sections of tumor.
Micro A13: Uninvolved kidney.
Micro A14: Tumor and tumor with respect to vein.

[page 2 of 2]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASH: [REDACTED]

PATIENT: [REDACTED]

Cytogeneticist: [REDACTED]

TCGA-CZ-5456

KARYOTYPE: T1: 46,XY[10] T2:46,XY[10]

METAPHASES COUNTED: 20 ANALYZED: 10 SCORED: 10 BANDING: GTG

INTERPRETATION:

Three different specimens from this tumor were received.

No cytogenetic aberrations were identified in metaphases analyzed from specimens labeled T1 and T2. These normal results do not exclude a neoplastic proliferation.

No metaphases were available from the specimen T3, therefore the cytogenetic analysis could not be performed.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

Renal Cell Carcinoma

[REDACTED]

Source: NCI Genomic Data Commons file 32d4efeb-cdb0-4de8-920f-99d9c3873d54 (TCGA-CZ-5456.46D64733-FBF3-4C27-9B4E-D5FB3F42CEFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).